Surgical pathology report (de-identified scan), TCGA case TCGA-A6-4105, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-A6-4105-01A (Primary Tumor).

[page 1 of 3]
SPECIMEN

- A. Right colon, segmental resection, sent for tissue procurement
- B. Apical lymph node
- C. Gallbladder

CLINICAL NOTES

PRE-OP DIAGNOSIS: Right colon tumor

GROSS DESCRIPTION

A. Received fresh for tissue procurement labeled "right colon" is a previously unopened 23 cm. segment of proximal right colon with attached 9.5 cm. of distal ileum surfaced by smooth to slightly scabrous tan pink serosa with a copious amount of attached mesentery and mesocolon. An unremarkable 5 cm. in length, 0.6 cm. in diameter appendix is present. The proximal and distal margins measure 4.4 and 6.5 cm. in circumference respectively. On opening there is a circumferential 8.0 x 5.3 cm. essentially necrotic rubbery tan white-red lesion located 4 cm. from the distal margin. On sectioning, the lesion has a maximal thickness of 2 cm., grossly extending through the muscularis to within 0.1 cm. of the closest inked free radial serosal surface. A portion of tumor and a portion of normal mucosa are submitted for tissue procurement as requested. The ileal and remaining colonic mucosa is unremarkable glistening tan pink with irregular folds and the walls average 0.6 cm. in thickness. Multiple soft tan pink to slightly rubbery tan white tissues in keeping with lymph nodes measuring up to 1 cm. in greatest dimension are recovered from the attached mesocolon and mesentery. Representative sections are submitted in 12 blocks as labeled. RS12.

BLOCK SUMMARY: 1 - Proximal and distal margin; 2-5 - tumor full thickness to inked free radial serosal surface; 6 - tumor to distal normal mucosa; 8 - random colon; 9 - appendix; 10-12 - six whole lymph nodes per cassette. [REDACTED].

GROSS DESCRIPTION

- B. Received in formalin, labeled "apical lymph node" is a 1.5 x 1 x 0.9 cm. rubbery pale tan-gold tissue in keeping with which is bisected and entirely submitted in one block. AS-1
- C. Received in bile-stained formalin labeled "gallbladder" is a predominantly intact 8.5 x 2.9 x 2.4 cm. gallbladder surfaced by smooth to focally cauterized tan-pink-red serosa with a 0.7 cm. length of attached cystic duct. The lumen contains a copious

[page 2 of 3]
amount of viscid olive green bile and multiple minute friable
green-black choleliths measuring up to 0.2 cm. The mucosa is
velvety
dark olive green, and the wall measures up to 0.5 cm.
Representative sections are submitted in two blocks as labeled.
RS-2

BLOCK SUMMARY: 1 - cystic duct margin and gallbladder neck, 2 -
body and fundus.

MICROSCOPIC DESCRIPTION

A. Microscopic examination of the right colon resection
reveals:

Histologic type: Invasive adenocarcinoma, not otherwise specified.

Histologic grade: Moderately differentiated.

Primary tumor (pT): Invasive through muscularis propria into
superficial fat (pT3).

Proximal margin: Negative for tumor.

Distal margin: Negative for tumor.

Circumferential (radial) margin: Negative for tumor.

Distance of tumor from closest margin: 4 cm. from distal margin

Vascular invasion: Not identified.

Regional lymph nodes (pN): Eighteen lymph nodes are dissected from

[page 3 of 3]
MICROSCOPIC DESCRIPTION

the specimen and they are all negative for metastatic tumor (pN0).
Non-lymph node pericolic tumor: Not identified.
Distant metastasis (pM): Could not evaluate, pMX.
Other findings: One small tubular adenoma is identified. The appendix is unremarkable. The ileocecal valve has fatty replacement. A representative tissue block (A2) is sent for MSI testing, as requested. This will be reported to office.

B. Microscopic examination of the apical lymph node reveals benign reactive follicular hyperplasia. No malignancy is identified. (0/1).

C. Microscopic examination of the gallbladder reveals chronic inflammation and adenomyosis.

5x1, 3x1, 2x1, 3260F

DIAGNOSIS

- A. Colon, right, segmental resection:
Invasive moderately differentiated adenocarcinoma, invasive into superficial fat (pT3).
Eighteen lymph nodes negative for metastatic tumor (0/18) (pN0).
Small tubular adenoma.
Unremarkable appendix.
Resection margins negative for carcinoma and for adenomatous epithelium.
- B. Apical lymph node, biopsy:
Reactive follicular hyperplasia, negative for malignancy.
- C. Gallbladder, excision:
Chronic calculous cholecystitis.
-

Source: NCI Genomic Data Commons file acaae88a-1731-4694-ac4e-b4389349a97a (TCGA-A6-4105.D2CE055F-3DE6-4B96-96AD-133091CD0A8F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).